Somatic mutation profile of tumor specimen BA2226D (aliquot aq-BA2226D) from BEATAML1.0 case 2014, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,466 days).
Specimen BA2226D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f24eb077-0d24-45c9-88e0-2d72137c4bd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2679D (Solid Tissue Normal), aliquot aq-BA2679D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1fcd2c4-101d-4a9d-870b-6f780ef46470

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2B | c.2203A>G p.K735E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs574099954; called by muse, varscan2
- SLC39A7 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2
- ZNF451 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TSC22D2 | c.1113C>A p.P371= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100721240; called by muse, mutect2
- HUWE1 | c.*20G>A | 3'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as rs377064040, COSV53334846; called by muse, mutect2, varscan2
